Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CU-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

Race: **WHITE**

Specimen #:

Taken:
Received:
Reported:

SPECIMEN:

A: SENTINEL LYMPH NODE #1 B: RIGHT BREAST TISSUE

10A-0-3

Carcinoma, infiltrating ductal, NOS 85009
Site: breast, NOS C50.9

FINAL DIAGNOSIS:

A. LYMPH NODE, SENTINEL #1, EXCISION:
- ISOLATED TUMOR CELLS IDENTIFIED.
- SEE COMMENT

1/25/11 *lu*

B. BREAST, RIGHT, SIMPLE MASTECTOMY:
- INFILTRATING DUCTAL CARCINOMA, MODERATELY DIFFERENTIATED (MODIFIED BLOOM RICHARDSON T=3, N=2, M1).
- TUMOR IS PRESENT WITHIN 0.1 CM OF INFERIOR-ANTERIOR MARGIN (B19)
- TUMOR DIMENSION (GREATEST): 3.4 CM
- NO DEFINITIVE LYMPH-VASCULAR INVASION IDENTIFIED.
- FIBROCYSTIC CHANGES INCLUDING STROMAL SCLEROSIS, CYST FORMATION, AND APOCRINE METAPLASIA.
- NIPPLE WITH NO SIGNIFICANT PATHOLOGICAL CHANGES
- AJCC PATHOLOGIC STAGE: pT2, pNO(i+), Mx

COMMENT:

Isolated tumor cells and clusters (less than 0.2 mm in dimension) are identified in the lymph node capsule on H&E examination and confirmed by a positive pancytokeratin immunohistochemical stain.

**** Report Electronically Signed Out ****

CLINICAL DIAGNOSIS AND HISTORY:

year-old female with right breast cancer.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION:

A. Received in formalin, labeled with the patient's name, , designated "SENTINEL LYMPH NODE #1" is a 2.0 x 1.0 x 0.5 cm yellow-white, soft tissue fragment. Bisected.

B. Received in fresh, labeled with the patient's name, .. designated "RIGHT BREAST TISSUE" is a 441.0 gram, simple mastectomy specimen, oriented with sutures (short superior, long lateral) measuring 20.0 x 15.5 x 3.2 cm. The overlying nipple/areolar complex measures 3.4 x 2.5 cm. Ink code: blue = superior-anterior, green = inferior-anterior, black = posterior. Sectioning reveals a 3.4 x 2.7 x 2.5 cm tumor with firm, tan, focally hemorrhagic cut surface in the lower outer quadrant. The tumor grossly involves the anterior margin, and is approximately 2.0 cm from the posterior margin. The remaining tissue is mostly fatty with admixed patches of white, fibrous tissue. This tissue is centrally adjacent to the tumor. Multiple tissue sections submitted for CBCP protocol with matching paraffin sections as follows:

Slide key:

- B1: Skin
- B2: Tumor with anterior margin
- B3: Tumor with anterior margin
- B4: Grossly normal fibrous, central, 2.0 cm from the tumor.
- B5: Representative nipple
- B6-B7: Representative upper outer quadrant.
- B8-B9: Representative lower outer quadrant.
- B10-B11: Representative upper inner quadrant.
- B12-B13: Representative lower inner quadrant.
- B14-B15: Representative tumor.
- B16-B19: Representative tumor. 19CF

Source: NCI Genomic Data Commons file 9b20d483-2a2b-4a58-97c2-b0b2b2d95316 (TCGA-A2-A0CU.D503E73D-8B94-46A0-A24F-93069A56DC7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).